FM case AD11605 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adnexal and Skin Appendage Neoplasms; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/efca050c-a37e-4754-8c1b-30af09ee6096

Male, 50.5 years: Adnexal carcinoma (ICD-O-3 8390/3) of the skin; metastasis biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
